Somatic mutation profile of tumor specimen TCGA-G4-6323-01A (aliquot TCGA-G4-6323-01A-11D-1719-10) from TCGA case TCGA-G4-6323, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IA; Age at diagnosis: 50.2 years (18,334 days).
Specimen TCGA-G4-6323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4598e6ba-bd22-4e75-a88d-cc6bfab807d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6323-10A (Blood Derived Normal), aliquot TCGA-G4-6323-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff102c7-30e6-4eeb-b9c4-19d1cb14fac1

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 21, Nonsense Mutation 10, Intron 3, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1958+1G>A p.X653_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | catalogued as rs1114167569, CD014920, CS011023, CS011024, HS080016, COSV57330281, COSV57355367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 28/56 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SUOX | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908007, CM971431; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV64103518; called by muse, mutect2, varscan2
- AGT | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs780763836, COSV64184019; called by mutect2, varscan2
- BAZ2A | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs368792704, COSV51633037; called by muse, mutect2, varscan2
- C3orf20 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs746325194, COSV53783083; called by muse, mutect2, varscan2
- CDK13 | c.3745C>G p.P1249A | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV51697268; called by muse, mutect2, varscan2
- CLEC3A | c.454G>A p.D152N (on ENST00000651443; = p.D143N on NM_005752.6) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100222257; called by muse, mutect2, varscan2
- CRYM | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs368131807, COSV54830101; called by muse, mutect2, varscan2
- CSF2RA | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV62623809; called by mutect2, varscan2
- CUX2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV99919863; called by muse, mutect2, varscan2
- EEF2K | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748609190, COSV53779384; called by muse, mutect2, varscan2
- ELOVL2 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 78/280 reads (28%) | catalogued as rs191521211, COSV61154333; called by muse, mutect2, varscan2
- ENTHD1 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1410497060, COSV57317911; called by muse, mutect2, varscan2
- FAM234B | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52193078; called by muse, mutect2, varscan2
- FREM1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs112925329, COSV63087185; called by muse, mutect2, varscan2
- FUCA1 | c.1267A>T p.M423L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65698780; called by muse, mutect2, varscan2
- GMEB2 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs776758045, COSV56606097; called by muse, mutect2, varscan2
- GON4L | c.4693G>T p.A1565S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV55188636; called by muse, mutect2, varscan2
- GPR3 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764550181, COSV64994541; called by muse, mutect2, varscan2
- HOXC10 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs750422553, COSV57725896; called by muse, mutect2, varscan2
- HS3ST4 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58805054, COSV58820680; called by muse, mutect2, varscan2
- HTT | c.3547C>T p.R1183* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV61858478; called by muse, mutect2, varscan2
- KCNB1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65566621; called by muse, mutect2, varscan2
- KCND2 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV58572065; called by muse, mutect2, varscan2
- KCNH1 | c.2233C>T p.R745* (on ENST00000271751 / NM_172362.3; = p.R718* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs1385878367, COSV55099082; called by muse, mutect2, varscan2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- LSM14A | c.716-1G>C p.X239_splice | Splice Site (SNP) | VAF 27/113 reads (24%) | catalogued as COSV70884770; called by muse, mutect2, varscan2
- MX2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs867413932, COSV58095491; called by muse, mutect2, varscan2
- NKX3-2 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV101219908; called by muse, varscan2
- NUDT5 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs779037273, COSV66718236; called by muse, mutect2, varscan2
- NYNRIN | c.5041C>T p.Q1681* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV101230621; called by muse, mutect2
- OR1C1 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs539224501, COSV68715493; called by muse, mutect2, varscan2
- OR51B6 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.281); catalogued as COSV66512420; called by muse, mutect2, varscan2
- OR5F1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs776485886, COSV99558685; called by muse, mutect2, varscan2
- PCDHAC2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs781959040, COSV53839739; called by muse, mutect2, varscan2
- PCDHGC5 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs143138320; called by muse, mutect2, varscan2
- PLCL1 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV70822718; called by muse, mutect2, varscan2
- PRSS48 | c.467T>A p.V156D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV71613587; called by muse, mutect2, varscan2
- RAB36 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1235271458, COSV54074152, COSV54076567; called by muse, mutect2, varscan2
- RGL3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs200127777, COSV62697358; called by muse, mutect2, varscan2
- RIMBP2 | c.2061G>C p.E687D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV55466932; called by muse, varscan2
- RIPOR3 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as rs780922865, COSV50390432; called by muse, mutect2, varscan2
- SCAPER | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100238517; called by muse, mutect2, varscan2
- SCFD2 | c.2030G>C p.R677P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV66369541; called by muse, mutect2, varscan2
- SERPINE2 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs757503754, COSV51456033; called by muse, mutect2, varscan2
- SHF | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52049676; called by muse, mutect2
- SIGLEC8 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as rs754606428, COSV58472567; called by muse, mutect2, varscan2
- SLC9B1 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 125/476 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56467866; called by muse, mutect2, varscan2
- TENM1 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.046); catalogued as rs377038677, COSV64426849; called by muse, mutect2, varscan2
- TMC2 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200272296, COSV100727628; called by muse, mutect2, varscan2
- TRAM1L1 | c.350del p.N117Tfs*24 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV100162353; called by mutect2, varscan2
- TRPM2 | c.4100G>T p.S1367I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV55966947; called by muse, mutect2, varscan2
- TSPOAP1 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52105356; called by muse, mutect2, varscan2
- VSTM2A | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 118/373 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56492666; called by muse, varscan2
- XPOT | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100225580; called by muse, mutect2, varscan2
- YIPF7 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs751659018, COSV60656180; called by muse, mutect2, varscan2
- ZCWPW2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 55/365 reads (15%) | catalogued as COSV67497882; called by muse, mutect2, varscan2
- ZMIZ2 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs772076174, COSV54806437; called by muse, mutect2, varscan2
- ZNF226 | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV100335171; called by muse, mutect2, varscan2
- ZNF507 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324195792, COSV61330313, COSV61332400; called by muse, mutect2, varscan2
- APC | c.4393_4394dup p.S1465Rfs*9 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- FOXC2 | c.1319T>G p.F440C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- GTSE1 | c.436_439dup p.L147Qfs*4 | Frame Shift Ins (INS) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- ACSF2 | c.693A>G p.E231= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99366217; called by muse, mutect2
- AP3D1 | c.2398A>C p.R800= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100642749; called by muse, mutect2
- COL18A1 | c.1590G>A p.A530= (on ENST00000359759 / NM_130444.3; = p.A295= on NM_030582.4) | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs758681240, COSV62699257; called by muse, mutect2, varscan2
- COP1 | c.930C>T p.S310= | Silent (SNP) | VAF 52/186 reads (28%) | catalogued as rs773369183, COSV100443398; called by muse, mutect2, varscan2
- CSMD2 | c.8550C>T p.S2850= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV53887686; called by muse, mutect2, varscan2
- EDARADD | c.570C>T p.D190= (on ENST00000334232 / NM_145861.4; = p.D180= on NM_080738.4) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs200017138, COSV62061563; called by muse, mutect2, varscan2
- EVC2 | c.3015G>T p.L1005= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV60388841; called by muse, mutect2, varscan2
- FBXO31 | c.936C>T p.H312= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs371017127, COSV61147408; called by muse, mutect2, varscan2
- GALNT2 | c.480T>C p.L160= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV64193391; called by muse, mutect2, varscan2
- IBSP | c.486C>T p.N162= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV56894518; called by muse, mutect2, varscan2
- IGKV1-12 | c.33G>T p.G11= | Silent (SNP) | VAF 151/676 reads (22%) | called by muse, mutect2, varscan2
- IL12B | c.510C>T p.C170= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs771036480, COSV51454347; called by muse, mutect2, varscan2
- MTMR9 | c.1188A>G p.V396= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs1193882989, COSV55310968; called by muse, mutect2, varscan2
- OR52E2 | c.483T>C p.S161= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV58612058, COSV58613580; called by muse, mutect2, varscan2
- PKNOX2 | c.558C>A p.P186= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53542265; called by muse, mutect2, varscan2
- POLM | c.855C>T p.D285= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV54241658; called by muse, varscan2
- REEP2 | c.555C>T p.D185= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99649655; called by muse, mutect2
- RNF213 | c.603A>G p.E201= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100173555; called by muse, varscan2
- SPTB | c.1785C>T p.T595= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs552724363, COSV67630278; called by muse, mutect2, varscan2
- TSPAN18 | c.444C>T p.C148= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs367945306; called by muse, mutect2, varscan2
- TTN | c.14508C>T p.V4836= (on ENST00000591111; = p.V3909= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs762428326, COSV59923210; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSH1 | c.456+10G>C | Intron (SNP) | VAF 36/183 reads (20%) | catalogued as COSV60241914; called by muse, mutect2, varscan2
- EDNRB | c.*1753A>G | 3'UTR (SNP) | VAF 176/458 reads (38%) | catalogued as COSV57519711; called by muse, mutect2, varscan2
- PNPO | c.417+322G>T | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as rs769609928, COSV56666016; called by muse, varscan2
- RBM44 | c.-98-3037A>G | Intron (SNP) | VAF 75/227 reads (33%) | catalogued as COSV57627709; called by muse, mutect2, varscan2
